Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6854, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6854-01A (Primary Tumor).

[page 1 of 3]
[illegible]

[page 2 of 3]
	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Sigmoid colectomy Specimen size: Not specified Tumor site: Sigmoid colon Tumor size: 8.5 x 4.5 x 1.5 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Pericolonic tissues Lymph nodes: 0/8 positive for metastasis (Regional 0/8) Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	--

Source: NCI Genomic Data Commons file 9fe42f3d-f85c-4bee-bee3-dbf76aec2efa (TCGA-F4-6854.7B65634E-37D9-4EDD-9B0A-E3EB627999B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).